TCGA case TCGA-TS-A7P0 — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Pennsylvania. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e23bc730-b369-4d6a-90ce-7223e234cd4d

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Dead; Days to death: 1,261 days (3.5 years).

Diagnoses (2)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 42.9 years (15,656 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Porfimer Sodium; Days to treatment start: 11 days; Days to treatment end: 11 days; Clinical trial indicator: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 43.6 years (15,933 days); Days to diagnosis: 277 days; Prior treatment: Yes.

Follow-up (2 entries)
- Day 277 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 277 days.
- Follow-up contact recording only the day: day 1,261.

Family history
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-TS-A7P0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 550 mg.
  Slide TCGA-TS-A7P0-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-TS-A7P0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-TS-A7P0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; History asbestos exposure: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- Drug treatment: Pharmaceutical therapy drug name: Porfimer Sodium (Photofrin).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,261 days; disease-specific survival: event status not recorded, 1,261 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 277 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-TS-A7P0-01A-11D-A34B-01): tumor purity 0.52, ploidy 3.9, whole-genome doublings 1.
